Gene-level copy-number profile of tumor specimen C3N-02375-01 (profiled together with C3N-02375-02) from CPTAC case C3N-02375, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 59.9 years (21,871 days).
Specimen C3N-02375-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fcef2185-cfe3-456e-8e06-3fa8672f8f62.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02375-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/e352ae1b-d586-4b9e-b2d6-c9d5f525280b

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 539; copy number 1: 4; copy number 2: 297; copy number 3: 13,907; copy number 4: 11,973; copy number 5: 14,482; copy number 6: 13,970; copy number 7: 709; copy number 8: 261; copy number 9: 583; copy number 10: 1,368; copy number 11: 10; copy number 12: 155; copy number 13: 497; copy number 14: 115; copy number 16: 12; copy number 18: 27.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:85,722,468–85,722,533, 1 gene (within-gene range 0–3): MIR4451.
- chr6:29,887,752–29,926,973, 5 genes (within-gene range 0–4): HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 816 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:129,555,214–129,918,575, 8 genes, copy number 16: PLXND1, RN7SL752P, AC023162.1, TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1.
- chr3:148,695,994–188,947,639, 668 genes, copy number 12–18 (within-gene range 7–18) (broad region; genes not listed).
- chr5:50,858,760–52,581,106, 22 genes, copy number 11–18: AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1.
- chr9:33,166,948–34,895,764, 87 genes, copy number 13 (within-gene range 4–13) (broad region; genes not listed).
- chr14:106,675,017–106,879,812, 26 genes, copy number 13 (within-gene range 9–13): IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr17:41,301,826–41,302,851, 1 gene, copy number 13: KRTAP29-1.
- chr19:40,121,311–40,226,697, 4 genes, copy number 16: VN1R96P, MAP3K10, TTC9B, CCNP.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
